Somatic mutation profile of tumor specimen 0DFF74 from CCDI case PBBSDG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.1 years (5,868 days).
Specimen 0DFF74: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcce86c5-f6e5-4047-b40f-9735ec5075bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFF71 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81b6cdfa-394f-45b1-bf18-6ccdf3e5c2fe

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFH | c.2889del p.F963Lfs*12 | Frame Shift Del (DEL) | VAF 118/828 reads (14%) | catalogued as COSV100809500; called by mutect2, varscan2
- PROB1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as rs980029928; called by muse, mutect2, varscan2
- ATXN3L | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 74/1397 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.535); called by muse, mutect2
- ATXN3L | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 73/1392 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, mutect2
- CECR2 | c.3754C>T p.P1252S (on ENST00000342247 / NM_001290047.2; = p.P1068S on NM_001290046.1) | Missense Mutation (SNP) | VAF 70/882 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.272); called by muse, mutect2
- PDHX | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 54/774 reads (7%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2
- DZIP3 | c.516A>G p.E172= | Silent (SNP) | VAF 84/1002 reads (8%) | called by muse, mutect2
- PRKACA | c.141C>T p.I47= | Silent (SNP) | VAF 105/951 reads (11%) | called by muse, mutect2, varscan2
